Gene-level copy-number profile of tumor specimen TCGA-AG-3890-01A from TCGA case TCGA-AG-3890, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.8 years (22,950 days).
Specimen TCGA-AG-3890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.7c734ff4-a570-47d3-b0dd-6a39b1073df8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3890-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a6c3687-c688-4320-a8a8-20d1124c7d48

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 876; copy number 2: 12,159; copy number 3: 28,925; copy number 4: 16,362; copy number 5: 147; copy number 6: 5; copy number 7: 1,311.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3890-01A-01D-1428-01): tumor purity 0.71, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:95,391,366–95,450,454, 2 genes: FAM81B, RTRAFP2.
- chr5:101,581,830–101,976,798, 3 genes: RN7SL802P, OR7H2P, AC117525.1.
- chr18:24,460,637–26,193,355, 22 genes (within-gene range 0–2): HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1.
- chr21:25,515,349–25,518,865, 1 gene: AP000221.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,311 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:87,250–21,535,665, 415 genes, copy number 7 (broad region; genes not listed).
- chr20:22,343,693–62,065,810, 896 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
